Somatic mutation profile of tumor specimen TCGA-Y8-A894-01A (aliquot TCGA-Y8-A894-01A-11D-A35Z-10) from TCGA case TCGA-Y8-A894, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.4 years (20,964 days).
Specimen TCGA-Y8-A894-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6f33123-e751-42eb-a2bd-1e603ed188b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A894-10A (Blood Derived Normal), aliquot TCGA-Y8-A894-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b995210f-4010-4517-a000-e97e6088a08e

The open-access MAF lists 87 somatic variants for this specimen: 69 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Nonsense Mutation 9, Frame Shift Del 6, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.3170T>A p.L1057* (on ENST00000280772 / NM_001320874.2; = p.L191* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 63/137 reads (46%) | catalogued as COSV99778908; called by muse, mutect2, varscan2
- ARIH1 | c.1532G>C p.R511P | Missense Mutation (SNP) | VAF 137/292 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101158641, COSV65912675; called by muse, mutect2, varscan2
- AXIN1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV51983334; called by muse, mutect2, varscan2
- BLM | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as rs1363297446, COSV100757066; called by muse, mutect2, varscan2
- C3orf38 | c.670T>A p.C224S | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV100007347; called by muse, mutect2, varscan2
- CAMK2B | c.1331C>A p.P444Q | Missense Mutation (SNP) | VAF 220/434 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.103); catalogued as COSV99322850; called by muse, mutect2, varscan2
- CAMK2N1 | c.77_79del p.S26del | In Frame Del (DEL) | VAF 43/71 reads (61%) | catalogued as rs757019600; called by mutect2, pindel, varscan2
- CARTPT | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99703924; called by muse, mutect2, varscan2
- CCDC63 | c.1553A>T p.Q518L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.022); catalogued as COSV99960667; called by muse, mutect2, varscan2
- CDKL5 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101184138; called by muse, mutect2, varscan2
- CFAP251 | c.2738A>G p.D913G | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99995844; called by muse, mutect2, varscan2
- DCTN4 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101437538; called by muse, mutect2, varscan2
- DICER1 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV100601889; called by muse, mutect2, varscan2
- ESPNL | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV100547670; called by muse, mutect2, varscan2
- FAM122A | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99598323; called by muse, mutect2, varscan2
- FAM91A1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 45/128 reads (35%) | catalogued as COSV58239138; called by muse, mutect2, varscan2
- FLT4 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as COSV99986300; called by muse, mutect2, varscan2
- GALNT7 | c.1766G>C p.G589A | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV99397060; called by muse, mutect2, varscan2
- GALNTL6 | c.1793A>G p.H598R | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV101560167; called by muse, mutect2, varscan2
- GBF1 | c.4222A>G p.T1408A (on ENST00000369983 / NM_001377137.1; = p.T1407A on NM_004193.3) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100890374; called by muse, mutect2, varscan2
- GGT5 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs372349468; called by muse, mutect2, varscan2
- GREB1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV99302439; called by muse, mutect2, varscan2
- HCFC1 | c.5614T>C p.C1872R | Missense Mutation (SNP) | VAF 166/342 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100128648; called by muse, mutect2, varscan2
- ITK | c.1416C>A p.Y472* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | catalogued as COSV101439667; called by muse, mutect2, varscan2
- KIF27 | c.2471G>T p.S824I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV99926797; called by muse, mutect2, varscan2
- LHX6 | c.428G>T p.W143L (on ENST00000373755 / NM_001242334.2; = p.W172L on NM_014368.5) | Missense Mutation (SNP) | VAF 88/138 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100493269; called by muse, mutect2, varscan2
- LRRC49 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 135/279 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99537113; called by muse, mutect2, varscan2
- MAPKAP1 | c.1316C>T p.A439V (on ENST00000265960 / NM_001006617.3; = p.A403V on NM_024117.3) | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.403); catalogued as COSV56366686; called by muse, mutect2, varscan2
- MARK2 | c.1786A>C p.T596P (on ENST00000402010 / NM_001039469.2; = p.T541P on NM_004954.5) | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100158261; called by muse, mutect2, varscan2
- MED12 | c.4021C>T p.R1341W | Missense Mutation (SNP) | VAF 241/490 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs777250096, COSV100376766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MON1A | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 43/95 reads (45%) | catalogued as COSV99616498; called by muse, mutect2, varscan2
- MYH8 | c.1216A>T p.R406W | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238110, COSV101238308; called by muse, mutect2, varscan2
- MYO5A | c.4664C>G p.S1555C | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100697431; called by muse, mutect2, varscan2
- PKHD1L1 | c.8355G>T p.K2785N | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV101005691; called by muse, mutect2, varscan2
- PLEKHG1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV100651527; called by muse, mutect2, varscan2
- PPM1M | c.509del p.G170Efs*33 (on ENST00000296487; = p.G331Efs*33 on NM_144641.4) | Frame Shift Del (DEL) | VAF 48/104 reads (46%) | catalogued as rs891143805; called by mutect2, pindel, varscan2
- PPP2R5E | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518435; called by muse, mutect2, varscan2
- PSMD2 | c.2039G>C p.R680T | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV100031608; called by muse, mutect2, varscan2
- PTRH1 | c.632C>A p.S211* | Nonsense Mutation (SNP) | VAF 48/150 reads (32%) | catalogued as COSV100076757; called by muse, mutect2, varscan2
- RRP12 | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as rs370146748, COSV59664597; called by muse, mutect2, varscan2
- RSPH3 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs775284185, COSV99396226; called by muse, mutect2, varscan2
- SOAT1 | c.1442T>G p.F481C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100858904; called by muse, varscan2
- STEAP4 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100112460; called by muse, mutect2, varscan2
- STX11 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 59/115 reads (51%) | catalogued as rs984594291, COSV100845473, COSV62450084; called by muse, mutect2, varscan2
- TAMALIN | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 33/63 reads (52%) | catalogued as COSV99531039; called by muse, mutect2, varscan2
- TENM3 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV101304956, COSV69315310; called by muse, mutect2, varscan2
- TEX11 | c.1685T>G p.L562W (on ENST00000344304; = p.L547W on NM_031276.3) | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721457; called by muse, mutect2, varscan2
- TLR3 | c.1513C>A p.L505I | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99710874; called by muse, mutect2, varscan2
- TRARG1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 83/150 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100416787; called by muse, mutect2, varscan2
- TSC22D1 | c.1090T>G p.L364V | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.452); catalogued as COSV101488075, COSV101488089; called by muse, mutect2, varscan2
- VAC14 | c.486+2T>A p.X162_splice | Splice Site (SNP) | VAF 143/348 reads (41%) | catalogued as COSV99934331; called by muse, mutect2, varscan2
- VCL | c.3291C>G p.N1097K (on ENST00000211998 / NM_014000.3; = p.N1029K on NM_003373.4) | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99280591; called by muse, mutect2, varscan2
- VGLL1 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101034584; called by muse, mutect2, varscan2
- YIPF6 | c.185T>A p.I62N | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101006200; called by muse, mutect2, varscan2
- ZNF148 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100642024; called by muse, mutect2, varscan2
- ZNF512B | c.1332A>G p.K444= | Splice Region (SNP) | VAF 42/96 reads (44%) | catalogued as COSV99411646; called by muse, mutect2, varscan2
- ZNF581 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV99553063; called by muse, mutect2, varscan2
- ANGPTL3 | c.1358dup p.T454Nfs*7 | Frame Shift Ins (INS) | VAF 162/346 reads (47%) | called by mutect2, varscan2
- CLUH | c.2175_2176del p.V726Sfs*4 (on ENST00000435359; = p.V765Sfs*4 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/181 reads (45%) | called by mutect2, pindel, varscan2
- COPG2 | c.2193C>A p.D731E | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- CPLANE2 | c.71dup p.Y24* | Nonsense Mutation (INS) | VAF 72/203 reads (35%) | called by mutect2, pindel, varscan2
- HSPA14 | c.1199del p.L400* | Frame Shift Del (DEL) | VAF 56/135 reads (41%) | called by mutect2, pindel, varscan2
- LRRC58 | c.527del p.N176Ifs*10 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- LRRK1 | c.3438del p.A1147Pfs*2 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- MUC5B | c.2829del p.C944Vfs*21 | Frame Shift Del (DEL) | VAF 51/130 reads (39%) | called by mutect2, pindel, varscan2
- PIGM | c.227dup p.Y76* | Nonsense Mutation (INS) | VAF 155/398 reads (39%) | called by mutect2, pindel, varscan2
- PRAMEF1 | c.1038_1039dup p.I347Kfs*28 | Frame Shift Ins (INS) | VAF 90/259 reads (35%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.344T>G p.I115R | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2
- ANKS1B | c.2532C>T p.S844= (on ENST00000547776 / NM_152788.4; = p.S70= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as rs1437820906, COSV100227443; called by muse, mutect2, varscan2
- CGNL1 | c.381T>C p.N127= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as COSV99847755; called by muse, mutect2, varscan2
- EIF2AK4 | c.1272G>A p.K424= | Silent (SNP) | VAF 66/134 reads (49%) | catalogued as rs1247515033, COSV99774295; called by muse, mutect2, varscan2
- ERBB2 | c.2263T>C p.L755= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV54062219, COSV54066696; called by muse, mutect2, varscan2
- ESPNL | c.1797G>A p.L599= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as COSV100547668; called by muse, mutect2, varscan2
- FBLN2 | c.30C>A p.A10= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV99851566; called by muse, mutect2, varscan2
- LAMB1 | c.3936A>T p.S1312= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV99740214; called by muse, mutect2, varscan2
- METTL21A | c.189G>A p.E63= | Silent (SNP) | VAF 11/157 reads (7%) | catalogued as rs746376776, COSV99777680; called by muse, mutect2
- MOV10 | c.1596C>A p.V532= | Silent (SNP) | VAF 82/194 reads (42%) | catalogued as COSV100659456; called by muse, mutect2, varscan2
- PSD4 | c.2745C>A p.P915= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV99830912; called by muse, mutect2, varscan2
- RHBDF2 | c.1101G>A p.R367= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as rs1240696987, COSV100489274; called by muse, mutect2
- RNF19B | c.603C>A p.P201= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs369366328, COSV99331230; called by muse, mutect2, varscan2
- SCAF11 | c.642T>C p.F214= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV101014147; called by muse, mutect2, varscan2
- SHISA2 | c.468G>T p.G156= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV100096318, COSV100096446; called by muse, mutect2, varscan2
- SNRPA1 | c.207G>A p.L69= | Silent (SNP) | VAF 96/376 reads (26%) | catalogued as rs1352816731, COSV99574477, COSV99574710; called by muse, mutect2, varscan2
- TJAP1 | c.6T>C p.T2= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV99446298; called by muse, mutect2, varscan2
- USF3 | c.3348A>T p.A1116= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV100324906; called by muse, mutect2, varscan2
- DYRK1A | c.1671+22T>A | Intron (SNP) | VAF 62/122 reads (51%) | catalogued as rs781196967, COSV100117610; called by muse, mutect2, varscan2
